FM case AD14532 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/245fb672-7572-4b93-99d6-a293aa9718f5

Male, 79.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
